Somatic mutation profile of tumor specimen TCGA-AB-2839-03B (aliquot TCGA-AB-2839-03B-01W-0728-08) from TCGA case TCGA-AB-2839, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.9 years (18,963 days).
Specimen TCGA-AB-2839-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e0e3c5c-3dee-45a3-a17c-97808c866de7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2839-11B (Solid Tissue Normal), aliquot TCGA-AB-2839-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/885df6c8-3588-4213-88e2-57572a08a810

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA1549L | c.4125dup p.T1376Hfs*62 (on ENST00000321505; = p.T1673Hfs*62 on NM_012194.3) | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | catalogued as rs752808243; called by pindel, varscan2
- PCDHAC1 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.501); catalogued as COSV53848236; called by muse, varscan2
- SLC1A1 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs749533772, COSV52052785; called by muse, mutect2, varscan2
